Surgical pathology report (de-identified scan), TCGA case TCGA-06-0152, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0152-01A (Primary Tumor).

PATH. NO:

06-0152

PATHOLOGICAL DIAGNOSIS:

BRAIN BIOPSY:

1. GLIOBLASTOMA.
2. RADIATION EFFECT.
-

Operation/Specimen:

Clinical History and Pre-Op Dx: Recurrent tumor.

GROSS PATHOLOGY: The specimen labeled "recurrent tumor", are multiple 0.5 to 2.5 cm. gray-white to tan tissue. Representative sections submitted in cassettes 1-5.

MICROSCOPIC: Sections reveal a glioblastoma with characteristic palisading necrosis. Also noted are changes consistent with radiation effect, such as coagulation necrosis, gliosis, sclerotic vessels and aggregates of macrophages. The proliferative index as measured by the MIB-1 stain is about 25%.

Source: NCI Genomic Data Commons file 61805560-e6c6-40ed-9185-93d2df00e922 (TCGA-06-0152.328704AB-7065-4E17-BA30-1A50B9949DD4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).